Somatic mutation profile of tumor specimen BA2163D (aliquot aq-BA2163D) from BEATAML1.0 case 2129, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.8 years (24,747 days).
Specimen BA2163D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9adf23e7-c519-442f-a619-1b6f395607a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2194D (Solid Tissue Normal), aliquot aq-BA2194D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11f2196d-c0c1-48a0-9bcb-5a30d49ccb9e

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Intron 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 46/120 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- TP53 | c.376-2A>G p.X126_splice | Splice Site (SNP) | VAF 75/146 reads (51%) | hotspot (GDC flag); catalogued as rs786202799, CS114003, COSV52689235, COSV52691326, COSV53121815, COSV53758902; ClinVar: likely pathogenic; called by muse, varscan2
- ADAM15 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as rs145412301; called by muse, varscan2
- FRYL | c.187A>G p.M63V | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as rs1476728171; called by muse, mutect2, varscan2
- NUP205 | c.4922C>A p.A1641E | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV53665106; called by muse, mutect2
- TXNL1 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 55/67 reads (82%) | SIFT tolerated (0.12); PolyPhen benign (0.352); catalogued as rs770023224, COSV54178147; called by muse, mutect2, varscan2
- DNMT3A | c.1709G>A p.G570E | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- EED | c.1092G>T p.W364C | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- EEF1AKNMT | c.1010C>G p.A337G (on ENST00000361735 / NM_015935.5; = p.A251G on NM_014955.3) | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.218); called by muse, varscan2
- INSM2 | c.1397C>A p.A466D | Missense Mutation (SNP) | VAF 98/227 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- KMT2A | c.3270G>A p.M1090I | Missense Mutation (SNP) | VAF 105/249 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- HYDIN | c.4425C>T p.I1475= | Silent (SNP) | VAF 49/126 reads (39%) | catalogued as rs752475652, COSV66832247; called by muse, mutect2, varscan2
- LRP1B | c.3939C>T p.Y1313= | Silent (SNP) | VAF 81/138 reads (59%) | catalogued as rs1299560554, COSV101255416; called by muse, mutect2, varscan2
- PADI1 | c.1737G>C p.A579= | Silent (SNP) | VAF 50/103 reads (49%) | catalogued as rs762129125; called by muse, mutect2, varscan2
- MBNL2 | c.994+1358C>T | Intron (SNP) | VAF 58/141 reads (41%) | catalogued as rs1360364352, COSV59121747; called by muse, mutect2, varscan2
- SCP2D1 | chr20:18809911 C>T | 5'Flank (SNP) | VAF 87/185 reads (47%) | catalogued as rs911051129; called by muse, mutect2, varscan2
- SLC25A13 | c.329-10759A>G | Intron (SNP) | VAF 20/58 reads (34%) | catalogued as rs1452262066; called by muse, varscan2
